Surgical pathology report (de-identified scan), TCGA case TCGA-DU-6410, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-6410-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

Med: Rec.: [REDACTED]

DOB: [REDACTED]

Phone Number: [REDACTED]

Gender: [REDACTED]

Location: [REDACTED]

Taken: [REDACTED]

Received: [REDACTED]

Reported: [REDACTED]

CLINICAL HISTORY

The patient is a [REDACTED]

[REDACTED] On imaging, there is a right frontal hemorrhagic lesion.

OPERATIVE DIAGNOSES

Right frontal mass

Operation/Specimen: A: Brain, right frontal mass, biopsy

B: Brain, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A. and B. Brain, right frontal tumor, biopsy: Anaplastic oligodendroglioma (WHO Grade III) (see comment).

COMMENT

The frozen section diagnosis is confirmed on permanent sections.

The biopsy shows brain tissue infiltrated by a neoplasm composed of mildly pleomorphic glial cells. The cells are tightly packed and demonstrate perinuclear clearing in some areas. Focal microvascular proliferation is also

seen in some areas along with frequent calcospherites. Areas of necrosis are

also noted. Mitoses range from 3 to 4 per ten 400x fields.

The tumor cells are diffusely highlighted by GFAP, while p53 stain shows

diffuse weak to moderate positivity of the tumor nuclei. CD163 stains rare

phagocytic cells. The Ki-67 labeling index is approximately 25%.

Positive and negative controls show appropriate immunoreactivity.

Molecular studies showed LOH for 1p/19q (see procedure addenda below).

[page 2 of 4]
PROCEDURES/ADDENDA

PCR for Epidermal Growth Factor Receptor

Date Ordered: [REDACTED] Date Reported: Pending

MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

Testing performed on paraffin tissue block

H stained slide was examined for subsequent tumor dissection.

Sufficient tumor cells were present in the tissue block and no microdissection was needed.

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter

have been shown to benefit from therapy with alkylating agents.

Assessment of

MGMT promoter methylation status involves bisulfite treatment of DNA followed

by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA

sequences. The analytic sensitivity of this assay was determined by serial

dilution of methylated positive control DNA into unmethylated DNA, and was

assessed to be 1% of methylated DNA in the background of unmethylated DNA.

Factors such as the presence of >50% non-neoplastic cells in the sample, or

extensive tissue necrosis, may preclude the detection of methylated MGMT

promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a

stand alone diagnostic test. This test was developed and its performance

characteristics determined by the [REDACTED] laboratory as required by [REDACTED] regulations. It has not been cleared or approved for

specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in

the context of established procedures and/or diagnostic criteria.

Interpretation

POSITIVE: Allelic loss on chromosome arm 1p and chromosome arm 19q is detected.

[page 3 of 4]
Informative loci are: D1S1592, D1S552, D19S219, D19S412, and PLA2G4C
Results-Comments

Test performed on DNA extracted from tumor tissue paraffin block and peripheral blood for germline comparison.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers

on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as

backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C

(with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4

nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the

first line markers at that chromosome arm are uninformative or otherwise

ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p

and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a

stand-alone diagnostic test. This test was developed and its performance

characteristics determined by the [REDACTED] laboratory as required by [REDACTED] regulations. It has not been cleared or approved for

specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in

the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample

may preclude the detection of allelic loss.

[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

A.

Brain, right frontal mass, biopsy: Glioma, low histological grade

[REDACTED] oligodendroglioma; limited sample, wait for permanents). [REDACTED] Touch preparation smears performed at [REDACTED] and results reported to

the Physician of Record. [REDACTED] [REDACTED]

[REDACTED]

GROSS DESCRIPTION

A.

[page 4 of 4]
"Right frontal mass," received fresh, two fragments, 1.3 cm across.
Soft,
greyish. In total, A1 and A2.

B.

Brain, excision biopsy:

CONTAINER LABEL: Right brain

FIXATIVE: fresh

GENERAL: Received is pink-tan to red soft tissue, aggregating to 4 x
3.9 x 0.6

SECTIONS: 3, [REDACTED]

L [REDACTED]

sar [REDACTED]

ICD-9(s):

239.6 239.6

Billing Fee Code(s):

Histo Data

Part A: Brain, right frontal mass, biopsy

Taken: [REDACTED] Received: [REDACTED]

Stain/cnt

CD163 Vector x 1

mGFAP-DA x 1

H/E x 1

LOH-curls x 1

MGMT-curls x 1

MIB1-DA x 1

P53DO7 x 1

TPS H/E x 1

H/E x 1

Part B: Brain, excision

Taken: [REDACTED] 00:00

Stain/cnt

H/E x 1

H/E x 1

H/E x 1

Block

Ordered

Comment

*** End of Report ***

Source: NCI Genomic Data Commons file e57a9336-9280-4731-a91f-e28150ac2c8d (TCGA-DU-6410.D7745E3B-3CCD-40FF-8634-9A0F71E088D4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).